Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7X3, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7X3-01A (Primary Tumor).

Name: [REDACTED]
Address: [REDACTED]
MR No.: [REDACTED]
Service: [REDACTED]
Surgeon: [REDACTED] M.D.

Surg. Path. No.: [REDACTED]
DOB: [REDACTED]
Sex/Race: F UNKNOWN
Location: [REDACTED]
Hosp. No.: [REDACTED]
Taken/Received: [REDACTED]

DIAGNOSIS

UTERUS, CERVIX. BIOPSY - SQUAMOUS CELL CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis), and that I have reviewed and approved this report.

[REDACTED] M.D.

[REDACTED] M.D.

SPECIMEN(S) SUBMITTED
CERVIX

HISTORY

The patient is a [REDACTED] year old woman with cervical carcinoma.
Operative procedure: Cervical biopsy.

GROSS

The specimen is received in a container of formalin, labeled with the patient's name and "cervical biopsy." It consists of multiple fragments of tan tissue measuring 0.7 x 0.5 x 0.1 cm in aggregate.
Jar 0. [REDACTED]

COMMENT

The cervical biopsy shows moderately differentiated, non-keratinizing squamous cell carcinoma with an intense stromal chronic inflammatory infiltrate. [REDACTED]

(End of Report)

ICD-O-3
Carcinoma, squamous cell non-keratinizing
Site Cervix NOS C53.9
8072/3
QD 10/10/13

Source: NCI Genomic Data Commons file 1a541e89-6b4f-4c08-9598-ddab17bbce19 (TCGA-C5-A7X3.34E0772A-D90C-48BE-86CF-E7968CADDFD7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).